Gene-level copy-number profile of tumor specimen ALCH-B027-TTP1-A from ALCHEMIST case ALCH-B027, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.3 years (18,370 days).
Specimen ALCH-B027-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 777e5d92-2146-4baf-b63f-78afa49fed70.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B027-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/04a1f3d3-f9db-41d4-87e2-7d8b25018885

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 4,480; copy number 2: 33,859; copy number 3: 12,488; copy number 4: 7,105; copy number 5: 239; copy number 6: 82; copy number 7: 1; copy number 8: 7; copy number 9: 7; copy number 10: 17.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr8:43,542,076–46,028,892, 4 genes: AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr15:25,187,536–25,230,919, 24 genes (within-gene range 0–1): SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33.
- chr15:77,613,027–77,926,846, 9 genes: LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1, CSPG4P13, AC104758.2, AC104758.3, RN7SL214P.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr18:46,326,809–48,863,217, 52 genes: RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1, SMAD2, MTCO2P2, AC120349.3, AC120349.1, AC120349.2, ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.
- chr20:3,659,248–3,876,123, 12 genes: GFRA4, ADAM33, SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 353 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,416,755–131,093,460, 30 genes, copy number 5: FAR2P2, KLF2P2, CYP4F62P, POTEI, RNU6-473P, AC013269.2, Metazoa_SRP, CFC1B, AC013269.1, PRSS40B, PRSS40A, AC140481.2, CFC1, Metazoa_SRP, POTEJ, RNU6-848P, CYP4F30P, AC140481.3, FAR2P3, KLF2P3, GPR148, AC140481.1, AMER3, CYCSP8, AC133785.1, ARHGEF4, AC112786.1, AC112786.2, SMIM39, FAM168B.
- chr2:167,954,020–168,247,595, 1 gene, copy number 9 (within-gene range 3–9): STK39.
- chr2:185,547,135–185,957,063, 6 genes, copy number 9: ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, RPL21P32.
- chr2:188,598,791–189,012,746, 6 genes, copy number 8: AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606.
- chr2:207,529,737–208,057,745, 17 genes, copy number 10 (within-gene range 3–10): CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17.
- chr2:242,088,633–242,175,634, 4 genes, copy number 6–8: LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr14:18,333,726–19,181,269, 38 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3, AL589743.3, NBEAP5, AL589182.2, OR11H13P.
- chr14:106,482,435–106,521,073, 7 genes, copy number 5 (within-gene range 4–5): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47.
- chr14:106,556,936–106,879,812, 51 genes, copy number 5: IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:45,214,448–45,615,945, 22 genes, copy number 5 (within-gene range 4–5): AC051619.9, AC051619.8, H3P39, AC051619.4, SLC28A2, AC051619.1, AC051619.2, RNU6-953P, GATM, AC025580.3, SPATA5L1, C15orf48, AC025580.1, MIR147B, AC025580.2, SLC30A4, HMGN2P46, SNORA41B, AC090527.1, DPPA5P2, AC090527.3, BLOC1S6.
- chr15:45,591,984–45,592,085, 1 gene, copy number 5 (within-gene range 4–5): Y_RNA.
- chr15:72,340,924–73,928,248, 40 genes, copy number 5 (within-gene range 2–5): HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, NPM1P42, NEO1, FKBP1AP2, NPM1P43, AC068397.1, HCN4, AC068397.2, REC114, MRPS15P1, NPTN, NPTN-IT1, CD276, AC022188.1, INSYN1, INSYN1-AS1, AC018943.1, TBC1D21, LOXL1-AS1.
- chr15:89,748,661–89,951,345, 14 genes, copy number 5: MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3.
- chr16:32,439,069–32,441,159, 1 gene, copy number 7: PABPC1P13.
- chr20:58,069,054–58,995,133, 30 genes, copy number 5: AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD.
- chr20:61,252,261–61,940,617, 6 genes, copy number 5: CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2.
- chr20:62,816,244–63,956,985, 72 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr21:46,458,891–46,691,226, 7 genes, copy number 6: DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 4,404. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
